Somatic mutation profile of tumor specimen TCGA-ET-A3DU-01A (aliquot TCGA-ET-A3DU-01A-11D-A19J-08) from TCGA case TCGA-ET-A3DU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 21.5 years (7,869 days).
Specimen TCGA-ET-A3DU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9439b8cf-aa85-43b4-84c4-9983d0829827.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3DU-10A (Blood Derived Normal), aliquot TCGA-ET-A3DU-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/670128ac-92b2-40be-952c-2c38dcf47c4a

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FCGBP | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs766907311; called by muse, mutect2, varscan2
- KMT2C | c.6551C>G p.S2184C | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV51427445; called by muse, mutect2
- TIPIN | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1357220802, COSV56019798; called by muse, mutect2
- TRPM3 | c.3925G>A p.E1309K (on ENST00000357533 / NM_001366142.2; = p.E1164K on NM_020952.6) | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs144341800, COSV62584082; called by muse, mutect2, varscan2
- ZGPAT | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456953260, COSV60831748; called by muse, mutect2, varscan2
- CACHD1 | c.1461G>A p.V487= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV51551590; called by muse, mutect2, varscan2
- PLP1 | c.549C>T p.T183= | Silent (SNP) | VAF 35/145 reads (24%) | catalogued as COSV58276141; called by muse, mutect2, varscan2
